Gene-level copy-number profile of tumor specimen TCGA-D8-A1XF-01A from TCGA case TCGA-D8-A1XF, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 46.0 years (16,787 days).
Specimen TCGA-D8-A1XF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.2084c32d-ed1a-43a7-adbb-ff2338363e11.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1XF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d1b84c6a-36c3-4ffc-a9f6-d063da8d56fc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,421; copy number 2: 15,742; copy number 3: 16,463; copy number 4: 18,036; copy number 5: 4,009; copy number 6: 1,064; copy number 7: 93; copy number 8: 97; copy number 9: 1,411; copy number 10: 132; copy number 11: 70; copy number 13: 26; copy number 14: 134; copy number 19: 30; copy number 23: 59; copy number 25: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1XF-01A-11D-A14F-01): tumor purity 0.78, ploidy 3.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:105,706,299–105,707,937, 1 gene: HSPD1P13.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,890 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:35,862,123–38,468,834, 68 genes, copy number 13–23 (within-gene range 3–23) (broad region; genes not listed).
- chr8:40,153,482–40,402,010, 4 genes, copy number 9: TCIM, AC022733.1, SIRLNT, AC105999.1.
- chr8:41,426,655–145,066,685, 1,609 genes, copy number 9–11 (broad region; genes not listed).
- chr11:61,102,489–61,295,316, 8 genes, copy number 13 (within-gene range 2–13): CD5, VPS37C, AP000437.1, PGA3, PGA4, AP003037.1, PGA5, VWCE.
- chr11:68,460,731–71,252,577, 67 genes, copy number 13–25 (broad region; genes not listed).
- chr11:73,308,276–77,477,030, 134 genes, copy number 14 (within-gene range 7–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
